Gene-level copy-number profile of tumor specimen TCGA-D3-A5GT-01A from TCGA case TCGA-D3-A5GT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 43.7 years (15,960 days).
Specimen TCGA-D3-A5GT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.6c437525-103a-4de7-ba1a-7d08d71ed633.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A5GT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13011e2d-9871-46a7-8b96-025db24e25d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,535; copy number 2: 31,840; copy number 3: 11,447; copy number 4: 6,379; copy number 5: 2,228; copy number 6: 390.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A5GT-01A-12D-A30W-01): tumor purity 0.87, ploidy 4.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,618 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:102,876,467–104,226,678, 17 genes, copy number 5 (within-gene range 4–5): COL11A1, SOD2P1, AC095032.2, AC095032.1, RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1, AMY1C, AL136455.1, AC092506.1, FTLP17.
- chr1:111,770,662–116,990,353, 118 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:119,368,779–121,580,524, 66 genes, copy number 6 (broad region; genes not listed).
- chr1:153,001,747–155,943,087, 181 genes, copy number 6 (broad region; genes not listed).
- chr1:164,555,584–164,899,296, 1 gene, copy number 5 (within-gene range 4–5): PBX1.
- chr1:164,680,085–165,827,755, 26 genes, copy number 5: AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1, AL451074.4.
- chr1:171,700,160–174,995,308, 64 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:181,317,690–183,145,592, 39 genes, copy number 5 (within-gene range 4–5): CACNA1E, Metazoa_SRP, RNA5SP70, AL161734.2, AL161734.1, RN7SKP229, AL391477.1, ZNF648, AL355482.1, AL355482.2, LINC01344, AL390856.1, YPEL5P1, RNU6-152P, AL513480.1, EIF1P3, GLUL, TEDDM1, LINC00272, RGSL1, AL139344.1, TEDDM2P, RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1.
- chr1:200,333,193–201,584,367, 32 genes, copy number 5 (within-gene range 4–5): AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, AC119427.1, TNNI1, AC096677.3, PHLDA3, AC096677.2, CSRP1, AC096677.1, RPS10P7.
- chr1:204,422,628–209,114,419, 122 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:209,173,014–209,173,375, 1 gene, copy number 5: AC092810.1.
- chr6:167,607–62,548,272, 1,540 genes, copy number 5 (broad region; genes not listed).
- chr15:84,570,649–101,933,350, 411 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,144. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
